Somatic mutation profile of tumor specimen TCGA-OR-A5KV-01A (aliquot TCGA-OR-A5KV-01A-11D-A29I-10) from TCGA case TCGA-OR-A5KV, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 17.1 years (6,250 days).
Specimen TCGA-OR-A5KV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0c4ebad-955f-4f37-8122-1ef52f72a56f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KV-10A (Blood Derived Normal), aliquot TCGA-OR-A5KV-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d24e872e-eca5-4c65-bfb1-9f55bdef375e

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 59/125 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C2CD5 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61726062; called by muse, mutect2, varscan2
- CACNA1F | c.4183G>A p.G1395R | Missense Mutation (SNP) | VAF 171/1280 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs370863603, COSV100544816, COSV59905779; called by muse, mutect2, varscan2
- PPDPFL | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs1327256996, COSV57460875, COSV57460969; called by muse, mutect2
- RYR2 | c.7423del p.V2475Sfs*28 | Frame Shift Del (DEL) | VAF 81/217 reads (37%) | catalogued as COSV63699897; called by mutect2, pindel, varscan2
- SSX3 | c.15C>A p.D5E | Missense Mutation (SNP) | VAF 406/2864 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs782165594; called by muse, varscan2
- ABI1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CHL1 | c.914A>T p.K305I (on ENST00000397491 / NM_001253387.1; = p.K321I on NM_006614.4) | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ELP1 | c.1052G>A p.W351* | Nonsense Mutation (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- PARP6 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCSK4 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- RAD17 | c.326A>T p.K109I (on ENST00000380774 / NM_133339.2; = p.K98I on NM_002873.1) | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SVEP1 | c.4981G>C p.G1661R | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBL7 | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 92/207 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- WDR72 | c.1068T>A p.D356E | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CENPF | c.4929C>G p.L1643= | Silent (SNP) | VAF 66/130 reads (51%) | catalogued as rs765485196; called by muse, mutect2, varscan2
- ENPP3 | c.1359C>T p.N453= | Silent (SNP) | VAF 100/242 reads (41%) | catalogued as rs368371746; called by muse, varscan2
- CPLANE1 | c.*2848G>A | 3'UTR (SNP) | VAF 18/318 reads (6%) | catalogued as rs752334335, COSV57052978; called by muse, mutect2
